Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MR, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MR-01A (Primary Tumor).

[page 1 of 2]
Specimen:
Procedure:
Accessioned:
Reported:
Submitting Phys:

Patient:
Medical Record #:
DOB/Age/Sex: (Age: M
Location/Client:

Surgical Pathology Report

Final Diagnosis

SPECIMEN LABELED AS "PHEOCHROMOCYTOMA" (A):

- PARAGANGLIOMA WITH FOCAL EXTENSION INTO ADIPOSE TISSUE.
- THE TUMOR FOCALLY EXTENDS TO THE INKED MARGIN.
- ONE LYMPH NODE NEGATIVE FOR TUMOR.
- SEE COMMENT.

Comment: The tumor measures 2.5 cm in greatest dimension. It appears to be associated with sympathetic ganglia. The Ki-67 labels index is moderately increased at >50 cells per medium field (20X) or >3% of tumor cells in the fields with highest labeling. The Ki-67 labels index is increased in the current material as compared to be previous adrenal gland pheochromocytoma.

SPECIMEN LABELED AS "PHEOCHROMOCYTOMA" (B):

- REACTIVE LYMPH NODE WITH LIPOGRANULOMAS.

Intradepartmental consultation with Dr.

***Report Electronically Signed By

D.***

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Intra-Operative Consultation with Frozen Section

A.F.S. ?? PHEOCHROMOCYTOMA:

- CONSISTENT WITH PARAGANGLIOMA ASSOCIATED WITH SYMPATHETIC GANGLION.

B.F.S. PHEOCHROMOCYTOMA:

- CONSISTENT WITH REACTIVE LYMPH NODE (2 FROZEN SECTIONS).

Clinical History

Pheochromocytoma status post surgery for same in

Pre-Operative Diagnosis

(Not Provided)

Post-Operative Diagnosis

(Not Provided)

[page 2 of 2]
Gross Description

A. ?? PHEOCHROMOCYTOMA (FRESH): The specimen, labeled with the patient's name and accession number, consists of a fragment of brown/yellow tissue measuring 2.5 x 2.5 x 1.1 cm with an irregular outer surface. Slicing reveals red beefy cut face. One slice is taken for frozen section and the frozen section residue is submitted in cassette A1. The remaining tissue is serially sliced and submitted in toto in cassettes A2-A4.

B. PHEOCHROMOCYTOMA (FRESH): The specimen, labeled with the patient's name and accession number, consists of two fragments of tissue. The biggest fragment of tissue measures 2.7 x 2.4 x 2.0 cm with an irregular outer surface. Slicing reveals yellow gray homogenous cut face. The second fragment of tissue measures 1.1 x 1 x 1 cm with irregular external surface. Slicing reveals yellow gray cut face. One slice is taken from both fragments of tissue for frozen sections and the frozen section residues are submitted into cassettes B1-B2 (B1, represents frozen section from biggest fragment of tissue, B2, represents frozen section residue from smaller fragment of tissue). The remaining larger fragment of tissue is submitted in toto in cassettes B3-B4 and the remaining smaller fragment of tissue is submitted in toto in cassettes B5-B6.

Department of Pathology
- End of Report -

Page 2 of 2
Printed:

Source: NCI Genomic Data Commons file 11eab9ad-6175-4b28-9b1d-1bea9e327fee (TCGA-SR-A6MR.563161BD-EC9E-4019-BCB6-1157F2DE9693.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).